CCDI case PBCEFL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2b066fd8-12a9-479c-822c-e053b56fc22b

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.0 years (3,635 days).

Biospecimens (3 samples)
- Sample 0DPZTF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPZTM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DPZUE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
